Gene-level copy-number profile of tumor specimen TCGA-A7-A4SE-01A from TCGA case TCGA-A7-A4SE, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 55.0 years (20,080 days).
Specimen TCGA-A7-A4SE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.7b527732-597f-49af-bf0c-69b485bbe511.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A7-A4SE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/51f528ce-d3b8-4a47-8808-8fa85c644601

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 1,212; copy number 2: 23,884; copy number 3: 8,047; copy number 4: 18,448; copy number 5: 3,737; copy number 6: 3,065; copy number 7: 257; copy number 8: 618; copy number 9: 168; copy number 10: 281; copy number 11: 27; copy number 14: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A7-A4SE-01A-11D-A25N-01): tumor purity 0.49, ploidy 3.21, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:152,320,544–152,536,092, 1 gene (within-gene range 0–8): FBXW7.
- chr4:152,448,275–153,415,118, 22 genes: AC023424.2, MIR3140, MIR4453HG, MIR4453, RPS3AP18, AC023424.1, TMEM154, AC106882.1, TIGD4, ARFIP1, NSA2P6, FAM192BP, AC093599.2, FHDC1, AC093599.1, TRIM2, AC013477.1, RNU6-1196P, Y_RNA, ANXA2P1, MND1, RN7SL419P.
- chr14:50,632,058–50,962,002, 14 genes: SAV1, RN7SL452P, AL606834.1, ZFP64P1, NIN, AL606834.2, AL133485.2, AL133485.3, AL133485.1, AL358334.1, PYGL, ABHD12B, AL358334.3, AL358334.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,170 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,048,576–157,437,754, 455 genes, copy number 8–11 (broad region; genes not listed).
- chr1:158,930,796–161,285,450, 113 genes, copy number 8–14 (within-gene range 3–14) (broad region; genes not listed).
- chr1:185,280,844–248,919,946, 1,288 genes, copy number 6–9 (broad region; genes not listed).
- chr3:11,745–13,283,281, 193 genes, copy number 5 (broad region; genes not listed).
- chr3:65,174,916–71,754,229, 58 genes, copy number 5–6 (within-gene range 4–6): LINC02040, MAGI1, AC121493.1, ILF2P1, RPL17P17, MAGI1-IT1, MAGI1-AS1, Y_RNA, AC106827.1, SLC25A26, RNU6-787P, RN7SL482P, LRIG1, AC104440.1, RPL21P41, AC098969.2, AC098969.1, AC020655.1, KBTBD8, MIR4272, AC114401.1, SUCLG2, NDUFB4P1, SUCLG2-AS1, TAFA1, COPS8P2, AC107626.1, AC104167.1, AC096922.1, PSMC1P1, TAFA4, RNA5SP135, EOGT, AC109587.1, TMF1, MIR3136, UBA3, ARL6IP5, LMOD3, FRMD4B, RBM43P1, AC099328.1, AC099328.2, AC104445.1, MITF, RN7SL418P, SAMMSON, AC139700.1, UQCRHP4, MDFIC2, AC104633.1, AC104633.2, COX6CP6, HMGB1P36, RNU6-281P, FOXP1, AC097634.4, FOXP1-AS1.
- chr3:94,506,766–107,240,671, 142 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr3:127,689,062–149,968,385, 399 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr4:145,335,263–152,318,364, 109 genes, copy number 8 (broad region; genes not listed).
- chr4:152,337,655–152,338,098, 1 gene, copy number 8: FBXW7-AS1.
- chr5:126,360,132–127,290,731, 22 genes, copy number 7: GRAMD2B, AC093535.1, AC093535.2, ALDH7A1, RNU6-290P, PHAX, AC099513.1, TEX43, BOLA3P3, HSPE1P10, LMNB1-DT, RNU6-752P, LMNB1, MARCHF3, C5orf63, AC005915.1, MRPS5P3, AC011416.1, SELENOTP2, AC011416.2, AC011416.3, AC011416.4.
- chr5:138,439,057–138,474,361, 4 genes, copy number 7: REEP2, AC113403.1, EGR1, RPL7P19.
- chr6:2,832,332–47,397,398, 1,311 genes, copy number 5–10 (broad region; genes not listed).
- chr6:127,266,682–131,469,536, 48 genes, copy number 6: RNF146, ECHDC1, RNA5SP217, YWHAZP4, RPL5P18, AL590002.1, AL096711.1, KIAA0408, AL096711.2, SOGA3, C6orf58, AL592291.1, AL356432.1, AL356432.3, AL356432.2, LINC02536, THEMIS, MRPS17P5, PTPRK, PTPRK-AS1, AL034349.1, EEF1DP5, Y_RNA, AL080315.1, Y_RNA, LAMA2, MESTP1, BMPR1AP1, RNU6-861P, AL356124.1, AL356124.2, ARHGAP18, RPL5P21, AL451046.2, B3GALNT2P1, AL451046.1, TMEM244, L3MBTL3, AL355581.1, SAMD3, TMEM200A, Y_RNA, AL583803.1, SMLR1, EPB41L2, AKAP7, AL137222.1, RPL21P67.
- chr6:134,169,246–135,260,933, 25 genes, copy number 6: SGK1, RPS29P32, RNA5SP218, Y_RNA, AL355881.1, KRT8P42, LINC01010, Z84486.1, CHCHD2P4, CT69, AL078590.2, FAM8A6P, AL078590.1, AL596188.1, AL121970.1, MEMO1P2, ALDH8A1, AL445190.1, HBS1L, MIR3662, AL353596.1, MYB, MYB-AS1, MIR548A2, AL023693.1.
- chr7:97,732,084–106,286,326, 279 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr7:148,940,265–149,334,857, 21 genes, copy number 9: AC073140.2, AC073140.1, RNY4, RNY3, RNY1, GHET1, PDIA4, RNU6-650P, COX6B1P1, ZNF786, ZNF425, RN7SL521P, ZNF398, AC004890.1, ZNF282, ZNF212, ZNF783, AC004890.3, AC004890.2, AC004941.2, NPM1P12.
- chr8:117,520,713–145,066,685, 488 genes, copy number 5 (broad region; genes not listed).
- chr9:14,475–17,503,923, 225 genes, copy number 5 (broad region; genes not listed).
- chr9:104,927,553–129,261,581, 456 genes, copy number 5 (broad region; genes not listed).
- chr11:22,829,380–22,945,393, 1 gene, copy number 6 (within-gene range 4–6): AC006299.1.
- chr11:23,154,683–23,203,161, 1 gene, copy number 6: LINC02718.
- chr11:28,702,607–38,014,141, 141 genes, copy number 6–10 (within-gene range 4–10) (broad region; genes not listed).
- chr12:58,872,149–60,419,293, 20 genes, copy number 7: LRIG3, AC068305.2, RPS6P22, AC068305.1, AC046129.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P, SLC16A7, AC079905.2, AC079905.1, AC080011.1, AC087883.2, AC087883.1, Y_RNA, AC090022.1, AC090022.2.
- chr13:44,094,822–46,897,076, 73 genes, copy number 6 (broad region; genes not listed).
- chr15:88,459,477–101,933,350, 344 genes, copy number 6 (broad region; genes not listed).
- chr19:13,795,460–42,295,797, 1,123 genes, copy number 5–7 (broad region; genes not listed).
- chr19:47,403,124–48,457,022, 48 genes, copy number 5: MEIS3, SLC8A2, AC073548.2, KPTN, NAPA-AS1, NAPA, AC073548.1, ZNF541, RN7SL322P, AC010519.1, AC010331.1, BICRA, BICRA-AS1, AC008985.1, EHD2, NOP53, SNORD23, NOP53-AS1, SELENOW, RPL23AP80, AC008745.1, TPRX1, CRX, TPRX2P, LINC01595, SULT2A1, BSPH1, ELSPBP1, CABP5, PLA2G4C, PLA2G4C-AS1, LIG1, AC011466.3, AC011466.2, ZSWIM9, CARD8, AC011466.4, AC011466.1, CARD8-AS1, ZNF114-AS1, ZNF114, CCDC114, EMP3, TMEM143, SYNGR4, KDELR1, GRIN2D, GRWD1.
- chr20:33,912,323–64,313,132, 782 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,212. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
